CDDP_EAGLE case CDDP-ABL8 — CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/6ae1ae28-be16-4182-ab15-f50a559bfcdd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Year of birth: 1943; Vital status: Dead; Days to death: 1,291 days (3.5 years); Year of death: 2006; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Age at diagnosis: 60 years; Year of diagnosis: 2003; Days to diagnosis: 0 days; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,291 days (3.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Exposures
- Exposure type: Tobacco; Pack years smoked: 25; Exposure duration years: 25.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CDDP-ABL8-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample CDDP-ABL8-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
  Slide CDDP-ABL8-TTP1-C-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Protocol status: Completed; Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); Cause of death: Submitted Malignancy and/or related tumor event; Height cm at diagnosis: 174 cm; Weight kg at diagnosis: 96 kg; History neoadjuvant treatment: No; Tobacco smoking history indicator: 3; Tobacco smoking year started: 1958; Tobacco smoking year stopped: 1983; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Partial Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Comorbidities: Comorbidity: Copd.
- Followup history list, Followup history 1: Tumor status: Never Tumor Free.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other Surgical Resection (Please Specify).
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- New tumor event 1: Days from index date to new tumor event diagnosis: 411; New tumor event type: Metastatic; New tumor event site: Brain; New event treatment outcome: Partial Response.
- New tumor event 2: Days from index date to new tumor event diagnosis: 414; New tumor event type: Metastatic; New tumor event site other: Adrenal Gland; New event treatment outcome: Partial Response.
